Somatic mutation profile of tumor specimen TCGA-32-4208-01A (aliquot TCGA-32-4208-01A-01D-1353-08) from TCGA case TCGA-32-4208, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.2 years (9,213 days).
Specimen TCGA-32-4208-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7b4623b-2833-47d5-afe7-e99e854e4870.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-4208-10A (Blood Derived Normal), aliquot TCGA-32-4208-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cebdfb08-9319-42df-942f-bee38568fc06

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 5, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 264/294 reads (90%) | hotspot (GDC flag); catalogued as COSV64870748; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 50/145 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 60/70 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCF2 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 12/271 reads (4%) | catalogued as COSV55182240; called by muse, mutect2
- ANO4 | c.1642G>C p.V548L (on ENST00000392977 / NM_001286615.2; = p.V513L on NM_178826.4) | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.42); catalogued as COSV54591874; called by muse, mutect2
- APC2 | c.5347G>A p.G1783R | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1366289919, COSV52017416; called by muse, mutect2
- C12orf60 | c.110T>G p.F37C | Missense Mutation (SNP) | VAF 48/436 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV57451619; called by muse, mutect2, varscan2
- CACNA1S | c.3286C>A p.R1096S | Missense Mutation (SNP) | VAF 229/544 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62938481; called by muse, varscan2
- CD177 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65121165; called by mutect2, varscan2
- CLCN4 | c.1757T>C p.V586A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66466047; called by muse, mutect2, varscan2
- CREBZF | c.410C>G p.S137W | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52629259, COSV99476455; called by muse, mutect2
- DOCK3 | c.4057G>C p.E1353Q | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56514080; called by muse, mutect2
- EPHX4 | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as COSV64889348; called by muse, mutect2, varscan2
- FAM20A | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs200466905, COSV56836359; called by muse, mutect2, varscan2
- FRY | c.5663A>G p.D1888G | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV66568173; called by muse, mutect2, varscan2
- GABRA2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV62913736; called by muse, mutect2, varscan2
- KCNH6 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376994110; called by muse, mutect2, varscan2
- LEMD3 | c.1771A>G p.I591V | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV57649635; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1736A>G p.Y579C | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64054466, COSV64055150; called by muse, mutect2, varscan2
- OSGEP | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1206143866, COSV51657375; called by muse, mutect2, varscan2
- PAN3 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 256/617 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs890741264, COSV66708213; called by muse, mutect2, varscan2
- PGK1 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV100965293; called by muse, mutect2
- PKHD1 | c.5959G>A p.A1987T | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.102); catalogued as rs375949362; called by muse, mutect2, varscan2
- RALYL | c.415T>C p.L139= | Splice Region (SNP) | VAF 18/41 reads (44%) | catalogued as COSV72819360; called by muse, mutect2, varscan2
- RAP2A | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV55354756; called by muse, mutect2, varscan2
- RHBDD1 | c.235T>C p.W79R | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV58125878; called by muse, mutect2, varscan2
- SPATA16 | c.490C>G p.H164D | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV63528338; called by muse, mutect2
- TMC5 | c.1604G>A p.C535Y (on ENST00000396229 / NM_001105248.1; = p.C289Y on NM_024780.5) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54902915; called by muse, mutect2, varscan2
- TNFSF10 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs755583625, COSV53842963; called by muse, mutect2, varscan2
- ABRAXAS1 | c.647_669del p.N216Rfs*14 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel
- BOK | c.362del p.G121Afs*18 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- CLK4 | c.768G>A p.L256= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV60318327; called by muse, mutect2, varscan2
- EXTL2 | c.855T>C p.H285= | Silent (SNP) | VAF 51/164 reads (31%) | catalogued as COSV64472941; called by muse, mutect2, varscan2
- MTHFD1L | c.2559C>T p.S853= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV66224764; called by muse, mutect2
- PGK1 | c.469C>T p.L157= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV100965294; called by muse, mutect2
- PLEC | c.12402C>G p.G4134= (on ENST00000322810 / NM_201380.4; = p.G4024= on NM_000445.5) | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV59623603; called by muse, mutect2, varscan2
- LINC02843 | n.454G>A | RNA (SNP) | VAF 30/74 reads (41%) | called by mutect2, varscan2
